TCGA case TCGA-A7-A0D9 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17baef7c-d97d-4b98-ab53-503ef856523d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 37 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 37.9 years (13,836 days); Year of diagnosis: 2009; Method of diagnosis: Core Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 125 days; Number of cycles: 4; Treatment dose: 4,320 mg; Prescribed dose: 1080; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 125 days; Number of cycles: 4; Treatment dose: 560 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 157 days; Treatment dose: 4,140 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 20; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 160 days; Disease response: Tumor Free.
- Days to follow up: 273 days; Disease response: Tumor Free.
- Days to follow up: 1,139 days (3.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ESR1 (IHC): Positive; Test value range: 90-99%.
- PGR (IHC): Negative; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A7-A0D9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,760 mg.
  Slide TCGA-A7-A0D9-01A-01-MS1: Section location: Bottom; Percent tumor cells: 10; Percent tumor nuclei: 55; Percent normal cells: 64; Percent necrosis: 1; Percent stromal cells: 25; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A0D9-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A0D9-01A-02-BS2: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A0D9-01A-03-BS3: Section location: Bottom; Percent tumor cells: 74; Percent tumor nuclei: 90; Percent normal cells: 15; Percent necrosis: 1; Percent stromal cells: 10; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A7-A0D9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A7-A0D9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A7-A0D9-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 1,830 mg.
  Slide TCGA-A7-A0D9-11A-05-TS5: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A0D9-11A-03-TS3: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Prospective collection: Yes; Retrospective collection: No; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Outer Quadrant; Anatomic organ subdivision: Left.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,139 days; disease-specific survival: no event (censored), 1,139 days; disease-free interval: no event (censored), 1,139 days; progression-free interval: no event (censored), 1,139 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A7-A0D9-01A-31D-A059-01): tumor purity 0.8, ploidy 2.2, whole-genome doublings 0.
